MMRF case MMRF_2047 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/edfc88a2-da96-4d8c-97ef-fcbcd4d2adb2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.0 years (24,822 days); ISS stage: I; Days to last known disease status: 910 days (2.5 years); Days to last follow up: 910 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 185 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 186 days; Days to treatment end: 186 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 1.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 22.4 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.84 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 9.36 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 8.6 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0.006 mg/dL.
- Day 78 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.24 mg/dL; Immunoglobulin G 5.29 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 3 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 4.75 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 7.26 mmol/L.
- Day 253 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 8.34 g/L; Immunoglobulin A 1.02 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 5.78 mmol/L.
- Day 344 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.72 mg/dL; Hemoglobin 8.93 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 4.95 mmol/L.
- Day 456: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL; Immunoglobulin G 7.47 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 8.14 mmol/L.
- Day 540 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.67 mmol/L.
- Day 624: M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 8.86 mmol/L.
- Day 708: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 7.9 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 7.48 mmol/L.
- Day 791: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.67 mg/dL; Immunoglobulin G 7.87 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 7.2 g/dL; Glucose 5.72 mmol/L.
- Day 910: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 8.04 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day -7: Weight: 101 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2047_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2047_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
